Gene-level copy-number profile of tumor specimen TCGA-DM-A285-01A from TCGA case TCGA-DM-A285, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.2 years (26,021 days).
Specimen TCGA-DM-A285-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.cdb9f6a7-f69e-4470-8eba-8c9cce7bcefc.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,190 have no estimate.
https://portal.gdc.cancer.gov/files/7f759eb1-1eb0-48bc-ba9e-0f1a5806e119

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,255; copy number 2: 36,024; copy number 3: 9,529; copy number 4: 3,293; copy number 5: 216; copy number 7: 116.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A285-01A-11D-A16U-01): tumor purity 0.71, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 332 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:73,346,936–73,675,450, 15 genes, copy number 7 (within-gene range 2–7): Y_RNA, ANXA7, AL512656.1, RPL26P6, MSS51, PPP3CB, PPP3CB-AS1, USP54, RNU6-883P, RPS26P41, AC073389.1, AC073389.3, MYOZ1, SYNPO2L, AC073389.2.
- chr10:73,674,295–73,730,487, 3 genes, copy number 7 (within-gene range 2–7): BMS1P4-AGAP5, BMS1P4, AC022400.4.
- chr10:73,715,843–84,518,521, 192 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr20:46,859,333–46,864,104, 2 genes, copy number 7: RN7SKP33, AL354766.1.
- chr20:48,324,812–54,269,542, 120 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,255. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
